Somatic mutation profile of tumor specimen TCGA-AB-2888-03A (aliquot TCGA-AB-2888-03A-01W-0732-08) from TCGA case TCGA-AB-2888, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.2 years (20,879 days).
Specimen TCGA-AB-2888-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bec78f7-e92b-4c32-9d96-2143c0810ff9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2888-11A (Solid Tissue Normal), aliquot TCGA-AB-2888-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fcb7b97-84cf-4ed8-9c86-554bfd8d61cc

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, In Frame Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HLA-B | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.262); catalogued as COSV69520663, COSV69521156; called by muse, mutect2, varscan2
- KIT | c.1254_1255insTTCTTC p.Y418_D419insFF | In Frame Ins (INS) | VAF 24/124 reads (19%) | catalogued as COSV55396258; called by mutect2, varscan2
- TTN | c.20192G>A p.R6731Q (on ENST00000591111; = p.R5804Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | PolyPhen possibly damaging (0.67); catalogued as rs148072021, COSV59923807, COSV59975784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSD17B1 | c.45C>T p.I15= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs775525762, COSV99864709; called by muse, mutect2
